Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4187, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4187-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Antrum. Tumor configuration: Ulcerating. Tumor size: 8 x 8 x 1.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Undifferentiated. Extent of invasion: Not specified. Lymph nodes: Not specified. Margins – Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 11986511-47ef-4e8a-a97c-378c94c5340e (TCGA-BR-4187.4220F8ED-DC92-460C-B254-44A8634F142B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).